Gene-level copy-number profile of tumor specimen TCGA-QR-A70R-01A from TCGA case TCGA-QR-A70R, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.6 years (15,917 days).
Specimen TCGA-QR-A70R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.ab32af2d-8294-45d1-9901-6a7300840aa8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A70R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/cd4dbef3-e51f-4527-985a-91c7238c41fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 13,297; copy number 2: 42,077; copy number 3: 4,379; copy number 4: 60.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:89,900,664–89,990,883, 1 gene (within-gene range 0–2): AC113167.1.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,911. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
